Somatic mutation profile of tumor specimen TCGA-A5-A0GX-01A (aliquot TCGA-A5-A0GX-01A-11W-A062-09) from TCGA case TCGA-A5-A0GX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 53.7 years (19,625 days).
Specimen TCGA-A5-A0GX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e4c85bf-13c3-47d7-95d3-ef1be36e175a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GX-10A (Blood Derived Normal), aliquot TCGA-A5-A0GX-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/085613fe-178d-4a2d-b599-71b9d1a8aaf8

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Nonsense Mutation 2, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 21/75 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AEBP2 | c.1403A>C p.H468P | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV56864120; called by muse, varscan2
- AGBL4 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs771499735, COSV61893448; called by muse, mutect2
- CADPS2 | c.3646G>T p.V1216L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV57367090; called by muse, mutect2, varscan2
- CTCF | c.1454A>G p.H485R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50472769; called by muse, mutect2
- DDX5 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56749401; called by muse, mutect2
- DNAH5 | c.8726G>A p.R2909H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756069405, COSV54231201, COSV54255638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM9B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.75); catalogued as COSV59119225; called by muse, mutect2, varscan2
- GMPR | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.936); catalogued as rs752563524, COSV52472328; called by muse, mutect2, varscan2
- HEATR1 | c.5866G>A p.G1956S | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780852573, COSV63981606; called by muse, mutect2, varscan2
- IDS | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV61712287, COSV61712661; called by muse, mutect2, varscan2
- KLHL41 | c.174C>G p.F58L | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52930533, COSV52931146; called by muse, mutect2, varscan2
- MED12 | c.4463G>A p.C1488Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61342661; called by muse, mutect2, varscan2
- MIER1 | c.451C>T p.R151C (on ENST00000355356 / NM_001077701.3; = p.R168C on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs752113662, COSV62530675; called by muse, mutect2, varscan2
- MYPN | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747665161, COSV62734796; called by muse, mutect2
- NPFFR2 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs751372382, COSV58150585; called by muse, mutect2, varscan2
- NXPE3 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs751813349, COSV56290308; called by muse, mutect2, varscan2
- OPRL1 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61091889; called by muse, mutect2
- POLA1 | c.2947A>G p.I983V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV66887102; called by muse, mutect2
- PTEN | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM110157, COSV64298007, COSV64299684, COSV64301059; called by muse, mutect2, varscan2
- SGSM1 | c.2761G>A p.G921S (on ENST00000400359 / NM_001039948.4; = p.G860S on NM_133454.3) | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs769748291, COSV63082509; called by muse, mutect2, varscan2
- TAS2R38 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.371); catalogued as rs1031089180, COSV71885578; called by muse, mutect2, varscan2
- THSD1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs201109452; called by muse, mutect2, varscan2
- ZNF229 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs775947315, COSV52162488; called by muse, mutect2, varscan2
- CREBBP | c.3684_3695del p.S1229_N1232del | In Frame Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel
- KITLG | c.307_330del p.K103_D110del | In Frame Del (DEL) | VAF 12/126 reads (10%) | called by mutect2, pindel
- PTEN | c.48_50del p.Y16_Q17delins* | Nonsense Mutation (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- COL4A5 | c.2484G>A p.G828= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100088113, COSV60360337; called by muse, mutect2, varscan2
- FGF2 | c.861G>A p.K287= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV52650502; called by muse, mutect2, varscan2
- GTPBP2 | c.315G>A p.G105= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV61076385; called by muse, mutect2, varscan2
- IGLV3-21 | c.246C>A p.G82= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- MCF2L2 | c.1230C>T p.D410= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as rs558392423, COSV61048947; called by muse, mutect2, varscan2
- PCDHGA7 | c.435T>C p.N145= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV53964420; called by muse, mutect2, varscan2
- DNM1P46 | n.1076G>T | RNA (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
